Somatic mutation profile of tumor specimen C3N-03473-01 (aliquot CPT0207090009) from CPTAC case C3N-03473, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 30.3 years (11,053 days).
Specimen C3N-03473-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1560163-b728-46e3-8b32-a3314aa09ecc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03473-31 (Blood Derived Normal), aliquot CPT0207150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e61c5d3-a0fb-4234-bb4c-2814da81cf79

The open-access MAF lists 47 somatic variants for this specimen: 29 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 16, Nonsense Mutation 4, In Frame Ins 2, Intron 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASCC1 | c.466C>T p.R156* (on ENST00000342444 / NM_001369085.1; = p.R128* on NM_001198798.2 and 8 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 108/236 reads (46%) | catalogued as rs183415577; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 23/85 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2
- CFAP43 | c.2275G>A p.D759N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs371818189, COSV53377858; called by muse, mutect2, varscan2
- DNTT | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 89/206 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs749423194; called by muse, mutect2, varscan2
- GIMAP7 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as rs763167681, COSV100543636; called by muse, mutect2, varscan2
- GK2 | c.32C>A p.P11Q | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV99081053; called by muse, mutect2
- GLI1 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 143/188 reads (76%) | SIFT tolerated (0.25); PolyPhen benign (0.044); catalogued as COSV57364738; called by muse, mutect2, varscan2
- GPAT4 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs746510734, COSV67840573; called by muse, mutect2, varscan2
- MAEA | c.409G>A p.G137S | Missense Mutation (SNP) | VAF 105/330 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs1011606213; called by muse, mutect2, varscan2
- OR51I1 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 51/104 reads (49%) | catalogued as rs757821983, COSV66507509; called by muse, mutect2, varscan2
- PPP1CC | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.072); catalogued as rs1391699210; called by muse, mutect2, varscan2
- PPP1R3C | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.066); catalogued as rs1442665745, COSV53288902; called by muse, mutect2, varscan2
- PXDNL | c.2558G>A p.R853Q | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100685516, COSV100687207; called by muse, mutect2
- SLX4 | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.122); catalogued as rs763869769; called by muse, mutect2, varscan2
- TP53 | c.466C>G p.R156G | Missense Mutation (SNP) | VAF 146/313 reads (47%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.6); catalogued as CD156964, COSV52711846, COSV52730924, COSV53119766; called by muse, varscan2
- ACTR1B | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHX40 | c.2233C>T p.Q745* | Nonsense Mutation (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2, varscan2
- FAM83B | c.958A>G p.R320G | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MTUS1 | c.520_522dup p.S174dup | In Frame Ins (INS) | VAF 7/61 reads (11%) | called by mutect2, pindel, varscan2
- MYO1E | c.2734A>G p.S912G | Missense Mutation (SNP) | VAF 134/339 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- NF1 | c.5135del p.P1712Lfs*8 (on ENST00000358273 / NM_001042492.3; = p.P1691Lfs*8 on NM_000267.3) | Frame Shift Del (DEL) | VAF 23/35 reads (66%) | called by mutect2, pindel, varscan2
- PLIN3 | c.461C>T p.T154I | Missense Mutation (SNP) | VAF 214/545 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PNPLA6 | c.2818C>G p.L940V (on ENST00000414982 / NM_001166111.2; = p.L892V on NM_006702.5) | Missense Mutation (SNP) | VAF 100/278 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- PTPRQ | c.5057C>T p.P1686L (on ENST00000616559; = p.P1644L on NM_001145026.2) | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- RING1 | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- SLK | c.1675C>T p.Q559* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- SUPT5H | c.3199A>G p.M1067V | Missense Mutation (SNP) | VAF 134/288 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- TP53 | c.481_483dup p.A161dup | In Frame Ins (INS) | VAF 112/342 reads (33%) | called by pindel, varscan2
- WDR7 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by mutect2, varscan2
- DNAJC13 | c.2679T>C p.D893= | Silent (SNP) | VAF 24/57 reads (42%) | called by muse, varscan2
- DOCK11 | c.876T>C p.D292= | Silent (SNP) | VAF 33/102 reads (32%) | called by muse, mutect2, varscan2
- DSP | c.8553C>T p.D2851= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as rs1554109307, COSV100673113; ClinVar: likely benign; called by muse, mutect2, varscan2
- EPHA7 | c.1131C>T p.G377= | Silent (SNP) | VAF 82/212 reads (39%) | catalogued as rs745756745, COSV65184907; called by muse, mutect2, varscan2
- FANCF | c.171T>G p.A57= | Silent (SNP) | VAF 209/481 reads (43%) | called by muse, mutect2, varscan2
- IQCN | c.3408G>A p.Q1136= | Silent (SNP) | VAF 83/169 reads (49%) | called by muse, mutect2, varscan2
- LAMB1 | c.2079C>T p.D693= | Silent (SNP) | VAF 102/230 reads (44%) | catalogued as rs778541187, COSV55966586; called by muse, mutect2, varscan2
- MAGEA10 | c.861T>C p.P287= | Silent (SNP) | VAF 31/328 reads (9%) | catalogued as rs745532310; called by muse, mutect2, varscan2
- NPEPL1 | c.1245C>T p.P415= | Silent (SNP) | VAF 97/222 reads (44%) | catalogued as rs752876660, COSV61937976; called by muse, mutect2, varscan2
- OGFR | c.1911C>T p.S637= | Silent (SNP) | VAF 228/681 reads (33%) | called by muse, varscan2
- SETDB1 | c.651C>T p.T217= | Silent (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- SUN2 | c.1104A>G p.Q368= | Silent (SNP) | VAF 112/271 reads (41%) | called by muse, mutect2, varscan2
- TXK | c.543A>G p.L181= | Silent (SNP) | VAF 53/101 reads (52%) | called by muse, mutect2, varscan2
- WNT9A | c.759G>T p.V253= | Silent (SNP) | VAF 28/298 reads (9%) | called by muse, mutect2
- WWP2 | c.1086C>T p.T362= | Silent (SNP) | VAF 111/307 reads (36%) | catalogued as rs774368555, COSV100598405, COSV100598543; called by muse, mutect2, varscan2
- ZNF135 | c.54C>T p.D18= | Silent (SNP) | VAF 59/125 reads (47%) | catalogued as rs764321307, COSV57883489; called by muse, mutect2, varscan2
- TMEM132B | chr12:125326603 C>G | 5'Flank (SNP) | VAF 51/144 reads (35%) | catalogued as rs1279550414; called by muse, mutect2, varscan2
- TTN | c.10360+2706G>A | Intron (SNP) | VAF 12/31 reads (39%) | catalogued as rs144909083; called by muse, mutect2, varscan2
